Somatic mutation profile of tumor specimen d945689a-dcf3-44f4-a42f-1ded6d (aliquot d945689a-dcf3-44f4-a42f-1ded6d_D6_1) from CPTAC case 02OV029, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB.
Specimen d945689a-dcf3-44f4-a42f-1ded6d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38e406d4-46b5-43a6-962a-3ae513f2339c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen e42b4c26-8c2b-444f-92f9-10c232 (Blood Derived Normal), aliquot e42b4c26-8c2b-444f-92f9-10c232_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b73c8a6-ad18-4f8b-aa2c-ca411117f6bf

The open-access MAF lists 96 somatic variants for this specimen: 69 protein-altering or splice-affecting, 16 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 16, Frame Shift Del 12, Intron 5, 3'UTR 2, In Frame Del 2, 5'Flank 1, RNA 1, Splice Region 1, Nonsense Mutation 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF10 | c.335A>T p.K112I (on ENST00000398564; = p.K88I on NM_014629.4) | Missense Mutation (SNP) | VAF 18/450 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as rs746676429; called by muse, mutect2
- CAPN1 | c.1951C>T p.L651F | Missense Mutation (SNP) | VAF 122/375 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99658969; called by muse, mutect2, varscan2
- CCDC83 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 21/167 reads (13%) | catalogued as COSV54703770; called by muse, mutect2, varscan2
- CLVS2 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 116/290 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.962); catalogued as COSV99253909; called by muse, mutect2, varscan2
- COG5 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51742803; called by muse, mutect2, varscan2
- CPS1 | c.4358G>T p.R1453L | Missense Mutation (SNP) | VAF 149/352 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM104560, COSV51805267; called by mutect2, varscan2
- DDX60L | c.3898G>A p.A1300T | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52713214; called by muse, varscan2
- ELAVL1 | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV60968669; called by muse, mutect2
- FOXN1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 250/316 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.413); catalogued as rs373326758; called by muse, mutect2, varscan2
- HPF1 | c.5T>A p.V2D | Missense Mutation (SNP) | VAF 52/69 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as rs1484028567; called by muse, mutect2, varscan2
- MED1 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 80/102 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs768315470; called by mutect2, varscan2
- MLN | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 97/217 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV56474810; called by muse, mutect2, varscan2
- NXPE1 | c.676T>C p.S226P (on ENST00000424269; = p.S84P on NM_152315.5) | Missense Mutation (SNP) | VAF 32/864 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs1332358992; called by muse, mutect2
- OR9K2 | c.736A>G p.I246V (on ENST00000305377; = p.I224V on NM_001005243.1) | Missense Mutation (SNP) | VAF 102/306 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1484600569; called by muse, mutect2
- PARP9 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 23/534 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64451584; called by muse, mutect2
- PREX2 | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55748462; called by muse, mutect2, varscan2
- RAG2 | c.1154del p.C385Ffs*59 | Frame Shift Del (DEL) | VAF 226/573 reads (39%) | catalogued as COSV57557933; called by mutect2, varscan2
- SLC10A4 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 101/192 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs761727427; called by muse, mutect2, varscan2
- SLC13A1 | c.793T>C p.F265L | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV52017525; called by muse, mutect2, varscan2
- SLFN12L | c.1676T>G p.L559W (on ENST00000260908 / NM_001363830.1; = p.L577W on NM_001195790.1) | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs757701863, COSV53471272; called by muse, mutect2, varscan2
- SLIRP | c.20G>T p.R7I | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs1457090032, COSV53173894, COSV53173921, COSV53174466; called by muse, mutect2, varscan2
- SNX19 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 340/810 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs750218534, COSV56288026; called by muse, mutect2
- SRRM2 | c.2764A>G p.I922V | Missense Mutation (SNP) | VAF 101/233 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs778128102; called by muse, mutect2, varscan2
- A4GNT | c.830C>G p.T277R | Missense Mutation (SNP) | VAF 119/562 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2
- ADAT1 | c.1226A>T p.D409V | Missense Mutation (SNP) | VAF 61/79 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- AGBL1 | c.1871T>A p.V624E | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ANK3 | c.3503_3540del p.E1168Gfs*7 (on ENST00000280772 / NM_001320874.2; = p.E302Gfs*7 on NM_001149.3) | Frame Shift Del (DEL) | VAF 107/280 reads (38%) | called by mutect2, pindel, varscan2
- API5 | c.613_627del p.Q205_G209del | In Frame Del (DEL) | VAF 51/255 reads (20%) | called by mutect2, pindel, varscan2
- B4GALNT4 | c.883C>G p.H295D | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BMPR1A | c.8A>G p.Q3R | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C10orf90 | c.721T>C p.S241P | Missense Mutation (SNP) | VAF 139/291 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C1GALT1C1L | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.024); called by mutect2, varscan2
- CATSPER1 | c.1193A>G p.E398G | Missense Mutation (SNP) | VAF 419/739 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by mutect2, varscan2
- CFL1 | c.282C>G p.S94R | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2
- CLOCK | c.108-3C>G | Splice Region (SNP) | VAF 62/174 reads (36%) | called by muse, mutect2, varscan2
- COL2A1 | c.3635G>T p.G1212V | Missense Mutation (SNP) | VAF 151/320 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP2C9 | c.373C>A p.R125S | Missense Mutation (SNP) | VAF 274/652 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- DNAH12 | c.3958C>A p.Q1320K (on ENST00000351747; = p.Q1343K on NM_001366028.2) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAH7 | c.4066G>A p.D1356N | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAJC24 | c.29del p.K10Rfs*18 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- DNLZ | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.1); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- E2F8 | c.925A>C p.K309Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM171B | c.2066_2096del p.F689* | Frame Shift Del (DEL) | VAF 96/321 reads (30%) | called by mutect2, pindel, varscan2
- FRZB | c.957C>A p.N319K | Missense Mutation (SNP) | VAF 89/187 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSIP2 | c.8401C>A p.L2801I | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GUCY2D | c.4_43delinsGC p.T2Afs*304 | Frame Shift Del (DEL) | VAF 78/97 reads (80%) | called by pindel, varscan2*
- HSPA8 | c.1780_1791del p.H594_K597del | In Frame Del (DEL) | VAF 17/84 reads (20%) | called by mutect2, pindel, varscan2
- INO80D | c.2237del p.T746Nfs*24 | Frame Shift Del (DEL) | VAF 254/584 reads (43%) | called by mutect2, varscan2
- KCNK18 | c.988G>C p.V330L | Missense Mutation (SNP) | VAF 38/587 reads (6%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.588); called by muse, mutect2
- KMT2D | c.6922G>T p.D2308Y | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- NAA80 | c.389T>G p.L130R (on ENST00000417393 / NM_001200018.2; = p.L152R on NM_012191.4) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- NCOR1 | c.2626G>A p.D876N | Missense Mutation (SNP) | VAF 111/142 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NOTCH2 | c.6713C>G p.A2238G | Missense Mutation (SNP) | VAF 196/491 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRK | c.2328_2337del p.S777Kfs*68 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | called by mutect2, pindel, varscan2
- PEX6 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 72/105 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- PI16 | c.180C>A p.D60E | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- PRIMPOL | c.495A>T p.K165N | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PXK | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- RNASEH2C | c.122_153del p.P41Hfs*54 | Frame Shift Del (DEL) | VAF 96/284 reads (34%) | called by mutect2, varscan2
- SARAF | c.843_870del p.R281Sfs*72 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- SETD3 | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- STAC3 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SV2B | c.1909_1916del p.G637Pfs*62 | Frame Shift Del (DEL) | VAF 24/154 reads (16%) | called by mutect2, pindel, varscan2
- TEC | c.1619_1625del p.S540Tfs*13 | Frame Shift Del (DEL) | VAF 93/208 reads (45%) | called by mutect2, pindel, varscan2
- TLR7 | c.2438C>A p.T813N | Missense Mutation (SNP) | VAF 116/277 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TNRC6A | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TONSL | c.3124G>A p.G1042S | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- VWCE | c.2576_2600del p.L859Hfs*4 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel
- ZNF587 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARHGAP19 | c.108G>A p.Q36= | Silent (SNP) | VAF 99/207 reads (48%) | called by muse, mutect2, varscan2
- C4A | c.2544G>A p.Q848= | Silent (SNP) | VAF 403/592 reads (68%) | catalogued as COSV71177922; called by muse, mutect2, varscan2
- EPGN | c.273T>C p.T91= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV59740598; called by muse, mutect2, varscan2
- HSD17B10 | c.243G>A p.K81= | Silent (SNP) | VAF 328/738 reads (44%) | called by muse, mutect2, varscan2
- IRAK3 | c.1341A>G p.Q447= | Silent (SNP) | VAF 59/126 reads (47%) | catalogued as rs1565813719, COSV54161584; called by muse, mutect2, varscan2
- KIF21A | c.4335A>T p.V1445= (on ENST00000361418 / NM_001378440.1; = p.V1432= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/296 reads (18%) | called by muse, mutect2, varscan2
- LPA | c.3489C>T p.P1163= | Silent (SNP) | VAF 47/138 reads (34%) | catalogued as rs758300066, COSV60300411; called by muse, mutect2, varscan2
- PPM1D | c.999G>A p.E333= | Silent (SNP) | VAF 69/80 reads (86%) | catalogued as rs1441865165; called by muse, mutect2, varscan2
- RPS6KA4 | c.1464C>T p.G488= | Silent (SNP) | VAF 104/287 reads (36%) | called by muse, mutect2, varscan2
- SPTY2D1 | c.534A>G p.K178= | Silent (SNP) | VAF 77/176 reads (44%) | called by muse, mutect2, varscan2
- TMC6 | c.276C>T p.R92= | Silent (SNP) | VAF 220/481 reads (46%) | catalogued as rs1200666811; called by muse, mutect2, varscan2
- TRMT44 | c.1317C>G p.S439= | Silent (SNP) | VAF 67/91 reads (74%) | catalogued as COSV67663396; called by muse, mutect2, varscan2
- TTN | c.17190A>G p.K5730= (on ENST00000591111; = p.K4803= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2, varscan2
- WIPI2 | c.675C>A p.T225= | Silent (SNP) | VAF 54/113 reads (48%) | called by muse, mutect2, varscan2
- ZNF646 | c.2025G>A p.R675= | Silent (SNP) | VAF 40/109 reads (37%) | called by muse, mutect2, varscan2
- ZYX | c.1485C>T p.D495= | Silent (SNP) | VAF 55/140 reads (39%) | catalogued as rs750816386; called by muse, mutect2, varscan2
- ADAMTS9 | c.1463+13C>A | Intron (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- ADRA1A | c.883+4969A>C | Intron (SNP) | VAF 56/68 reads (82%) | called by muse, mutect2, varscan2
- COL25A1 | c.*10C>A | 3'UTR (SNP) | VAF 30/52 reads (58%) | called by muse, mutect2, varscan2
- DNAH8 | c.11874+39C>T | Intron (SNP) | VAF 44/102 reads (43%) | called by muse, mutect2, varscan2
- EGFEM1P | n.725G>A | RNA (SNP) | VAF 34/243 reads (14%) | catalogued as rs144046880; called by muse, mutect2, varscan2
- LGR6 | chr1:202189258 C>T | 5'Flank (SNP) | VAF 98/229 reads (43%) | called by muse, mutect2, varscan2
- LRCH1 | c.-17G>A | 5'UTR (SNP) | VAF 48/57 reads (84%) | called by muse, mutect2, varscan2
- MAP4 | c.2000-13816T>G | Intron (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- PNMA6A | chrX:153075770 T>A | 3'Flank (SNP) | VAF 10/37 reads (27%) | called by mutect2, varscan2
- RYR1 | c.*51G>A | 3'UTR (SNP) | VAF 80/98 reads (82%) | catalogued as rs1210346687; called by muse, mutect2, varscan2
- SLC22A20P | n.1081+2074_1081+2109del | Intron (DEL) | VAF 59/206 reads (29%) | called by mutect2, pindel
